Gene-level copy-number profile of tumor specimen ALCH-B363-TTP1-A from ALCHEMIST case ALCH-B363, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 55.3 years (20,202 days).
Specimen ALCH-B363-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 97d1b5f3-46c3-4148-8d10-0404468196e3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B363-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,240 have no estimate.
https://portal.gdc.cancer.gov/files/4642100a-c628-4f98-b48b-41613f337f07

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 66; copy number 1: 405; copy number 2: 57,442; copy number 3: 378; copy number 4: 61; copy number 5: 26; copy number 8: 1; copy number 9: 1; copy number 10: 2; copy number 17: 1.

Homozygous deletions (total copy number 0; autosomes only): 58 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,211,340–1,214,153, 1 gene: TNFRSF4.
- chr1:1,275,223–1,292,029, 2 genes: LINC01786, SCNN1D.
- chr1:1,311,585–1,335,314, 5 genes (within-gene range 0–5): INTS11, MIR6727, AL139287.1, CPTP, TAS1R3.
- chr1:1,352,689–1,375,495, 2 genes: MXRA8, AURKAIP1.
- chr1:47,761,132–47,765,547, 1 gene (within-gene range 0–2): AL691459.1.
- chr2:89,872,463–89,887,247, 3 genes: IGKV2D-38, IGKV1D-37, IGKV2D-36.
- chr2:90,100,236–90,100,738, 1 gene: IGKV1D-16.
- chr2:90,121,786–91,621,421, 15 genes (within-gene range 0–1): IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118, AC233263.1, AC233266.1, AC233266.2, AC116050.1.
- chr2:91,684,447–91,767,701, 6 genes (within-gene range 0–3): DRD5P1, AC027612.2, NKAIN1P2, AC027612.1, KMT5AP2, AC027612.3.
- chr4:49,486,926–49,524,185, 5 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8.
- chr6:31,528,114–31,530,232, 2 genes (within-gene range 0–4): RPL15P4, MCCD1.
- chr9:36,856,555–36,861,375, 1 gene (within-gene range 0–2): AL450267.1.
- chr9:68,328,308–68,531,061, 4 genes (within-gene range 0–4): PGM5, PGM5-AS1, AL161457.2, AL161457.1.
- chr12:31,012,503–31,015,806, 1 gene: AC008013.2.
- chr16:46,469,341–46,626,992, 7 genes: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1.
- chr16:46,702,282–46,790,407, 1 gene (within-gene range 0–2): MYLK3.
- chr17:183,824–191,587, 1 gene: LINC02091.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 31 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,059,708–1,074,306, 3 genes, copy number 5: AL390719.1, AL645608.8, RNF223.
- chr1:1,167,104–1,167,198, 1 gene, copy number 8: MIR200B.
- chr1:1,203,508–1,206,592, 1 gene, copy number 9: TNFRSF18.
- chr1:1,292,390–1,309,609, 1 gene, copy number 5 (within-gene range 3–5): ACAP3.
- chr1:1,308,597–1,311,677, 1 gene, copy number 5 (within-gene range 0–5): PUSL1.
- chr1:1,335,276–1,349,418, 2 genes, copy number 5 (within-gene range 0–5): DVL1, MIR6808.
- chr1:2,632,568–2,636,620, 1 gene, copy number 5 (within-gene range 2–5): MMEL1-AS1.
- chr4:1,574,062–1,580,253, 1 gene, copy number 10: AC147067.1.
- chr6:29,790,954–29,797,811, 2 genes, copy number 5: HLA-V, HCG4.
- chr6:30,001,011–30,061,640, 1 gene, copy number 5 (within-gene range 2–5): ZNRD1ASP.
- chr6:30,031,713–30,064,909, 5 genes, copy number 5: ETF1P1, AL669914.3, AL669914.2, POLR1H, AL669914.4.
- chr6:30,282,349–30,286,054, 1 gene, copy number 5 (within-gene range 3–5): AL662795.2.
- chr6:32,517,353–32,530,287, 1 gene, copy number 17: HLA-DRB5.
- chr6:32,578,769–32,589,848, 1 gene, copy number 5: HLA-DRB1.
- chr14:105,583,731–105,588,395, 1 gene, copy number 10: IGHA2.
- chr16:88,382,959–88,537,031, 4 genes, copy number 5 (within-gene range 5–8): ZNF469, ZFPM1, MIR5189, AC116552.1.
- chr16:88,803,789–88,809,258, 1 gene, copy number 5: CDT1.
- chr19:1,103,926–1,174,268, 2 genes, copy number 5: GPX4, SBNO2.
- chr20:62,477,870–62,478,594, 1 gene, copy number 5: AL499627.2.

Autosomal genes at a single copy (total copy number 1): 380. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
